FM case AD9917 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/d8bbb91d-60bc-44f9-8b2f-d8d9bd432356

Male, 71.6 years: diagnosis not reported by GDC; metastasis biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
